Somatic mutation profile of tumor specimen TCGA-YT-A95D-01A (aliquot TCGA-YT-A95D-01A-11D-A428-09) from TCGA case TCGA-YT-A95D, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymoma, type AB, NOS; Tissue or organ of origin: Anterior mediastinum; Age at diagnosis: 50.3 years (18,363 days).
Specimen TCGA-YT-A95D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68841431-7f03-4f6e-8b51-2ac28f548b8d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YT-A95D-10A (Blood Derived Normal), aliquot TCGA-YT-A95D-10A-01D-A42B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3351696a-9491-41ab-87bd-3f1bb585ea71

The open-access MAF lists 18 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 12, Silent 3, Frame Shift Ins 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 150/507 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2, varscan2
- EBI3 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as rs1466404008, COSV55690473; called by muse, mutect2
- FAM3A | c.64G>A p.V22M | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs782638937, COSV59194560; called by muse, mutect2, varscan2
- HM13 | c.989C>T p.P330L | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1212555754; called by muse, mutect2
- MTOR | c.699G>T p.W233C | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs1306389306, COSV63880196; called by muse, mutect2
- MYH14 | c.2231G>A p.R744Q | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1442852878; called by muse, mutect2
- NEB | c.8423C>T p.A2808V | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.54); catalogued as COSV51419334; called by muse, mutect2, varscan2
- PLCB1 | c.594G>T p.R198S | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as COSV62049648; called by muse, mutect2
- GARNL3 | c.2407G>A p.A803T | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.82); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KRT78 | c.179del p.G60Vfs*27 | Frame Shift Del (DEL) | VAF 22/59 reads (37%) | called by pindel, varscan2*
- LRFN2 | c.537C>G p.S179R | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- OTUD3 | c.267dup p.R90Tfs*22 | Frame Shift Ins (INS) | VAF 32/105 reads (30%) | called by mutect2, pindel, varscan2
- OVCH1 | c.2683C>A p.L895M | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.77); called by muse, mutect2
- PLAG1 | c.1271T>G p.F424C | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ZNF451 | c.2101dup p.T701Nfs*2 | Frame Shift Ins (INS) | VAF 16/58 reads (28%) | called by mutect2, pindel, varscan2
- OCRL | c.531C>A p.P177= | Silent (SNP) | VAF 79/180 reads (44%) | called by muse, mutect2, varscan2
- PLXND1 | c.1881G>T p.L627= | Silent (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2
- YARS2 | c.225C>T p.T75= | Silent (SNP) | VAF 31/82 reads (38%) | catalogued as rs376399300; called by muse, mutect2, varscan2
